Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A17S, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A17S-01A (Primary Tumor).

[page 1 of 4]
Adenocarcinoma, Endometrioid, NOS

8380/3 12/9/10

Site Code: Endometrium: C54.1

Surgical Pathology

DIAGNOSIS:

A. Uterus, bilateral ovaries, and fallopian tubes; hysterectomy and bilateral salpingo-oophorectomy: Endometrial adenocarcinoma, endometrioid type, FIGO grade 1 (of 3) is identified forming a mass (4.8 x 3.1 x 2.3 cm) circumferentially involving the endometrial cavity. The tumor invades 0.4 cm into the myometrium (total myometrial thickness, 2.2 cm). The tumor does not involve the endocervix. Lymphovascular space invasion is not identified. The margins are negative for tumor. The bilateral ovaries and fallopian tubes show no diagnostic abnormalities. [AJCC pT1bNOMx]

B. Gallbladder, cholecystectomy: Chronic cholecystitis with cholelithiasis containing multiple mixed stones ranging in size from 0.6 cm to 3.4 cm in greatest dimension. An adenomyoma is also present. A single benign cystic duct lymph node is identified.

C. Lymph nodes, left pelvic, dissection: Multiple (25) left pelvic lymph nodes are negative for tumor.

D. Lymph nodes, right pelvic, dissection: Multiple (27) right pelvic lymph nodes are negative for tumor.

This final pathology report is based on the gross/macroscopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes

[page 2 of 4]
identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

A. Received fresh labeled "uterus, bilateral tubes and ovaries" is a 220.0 gram uterus and cervix with attached bilateral tubes and ovaries. The uterine serosa is smooth. There is a 4.8 x 3.1 x 2.3 cm polypoid mass in the left side of the endometrial cavity which grossly appears to invade 0.4 cm into the 2.2 cm thick myometrium. There are no leiomyomas. There is a 2.3 x 1.6 x 1.4 cm right ovary with a smooth outer surface and a solid cut surface with a 7.2 x 0.4 cm right fallopian tube. There is a 2.7 x 1.6 x 1.2 cm left ovary with a smooth outer surface and a cystic and solid cut surface with a 6.9 x 0.4 cm left fallopian tube. Representative sections submitted.

B. Received fresh labeled "gallbladder" is a 6.2 x 2.7 x 2.7 cm gallbladder with a 0.4 maximum wall thickness and patent cystic duct. A cystic duct lymph node is identified. Multiple mixed stones (ranging in size from 0.6 cm to 3.4 cm in greatest dimension) are identified, including two stones incarcerated in the neck. No masses are grossly identified. Representative sections are submitted.

C. Received fresh labeled "left pelvic lymph nodes" is a 10.2 x 7.9

[page 3 of 4]
x 2.0 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted.

D. Received fresh labeled "right pelvic lymph nodes" is a 11.5 x

6.5 x 2.5 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

BLOCK SUMMARY:

Part A: Uterus, bilateral tubes and ovaries

- 1 Left cornu mass 1
- 2 Left cornu mass 2
- 3 Left cornu mass 3
- 4 Intrauterine mass 1
- 5 Intrauterine mass 2
- 6 Right ovary
- 7 Right fallopian tube
- 8 Post uterine wall
- 9 Left ovary
- 10 Left fallopian tube
- 11 Endometrium polyp 1
- 12 Endometrium polyp 2
- 13 Endometrium polyp 3
- 14 Endometrium polyp 4
- 15 Lower uterine segment

Part B: Gallbladder

- 1 Gallbladder fundus
- 2 Pericystic duct LN
- 3 Gallbladder body
- 4 Cystic duct margin

Part C: Left Pelvic Lymph Nodes

- 1 Left pelvic LN 1(C1)
- 2 Left pelvic LN 4(C2)
- 3 Left pelvic LN 3(C3)
- 4 Left pelvic LN 5(C4)
- 5 Left pelvic LN 2(C5)
- 6 Left pelvic LN 4(C6)
- 7 Left pelvic LN 3(C7)
- 8 Left pelvic LN 3(C8)
- 9 Left pelvic LN 3(C9)
- 10 Left pelvic LN 2(C10)
- 11 Left pelvic LN 1of2(C11)

[page 4 of 4]
12 Left pelvic LN 2of2 (C11)
13 Left pelvic LN 1of5 (C12)
14 Left pelvic LN 2of5 (C12)
15 Left pelvic LN 3of5 (C12)
16 Left pelvic LN 4of5 (C12)
17 Left pelvic LN 5of5 (C12)

Part D: Right Pelvic Lymph Nodes

1 Rt pelvic lns 4 (D1)
2 Rt pelvic lns 4 (D2)
3 Rt pelvic lns 4 (D3)
4 Rt pelvic lns 1 (D4)
5 Rt pelvic lns 1 (D5)
6 Rt pelvic lns 3 (D6)
7 Rt pelvic lns 2 (D7)
8 Rt pelvic lns 1 (D8)
9 Rt pelvic lns 4 (D9)
10 Rt pelvic lns 2 (D10)
11 Rt pelvic lns 1 (D11)
12 Rt pelvic lns 1 (D12)
13 Rt pelvic lns 1of2 (D13)
14 Rt pelvic lns 2of2 (D13)

Source: NCI Genomic Data Commons file f259cf65-8a01-477b-adf6-86c2840d0bb8 (TCGA-D1-A17S.54337BED-9366-4CB6-BA95-BB5999CBF342.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).